Somatic mutation profile of cancer-model specimen HCM-CSHL-0658-C20-85O (3D Organoid, passage 4; aliquot HCM-CSHL-0658-C20-85O-01D-A85K-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0658-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 59.9 years (21,879 days).
Specimen HCM-CSHL-0658-C20-85O: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08e74431-c3fc-4dde-90dd-11abedd4fe31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0658-C20-10A (Blood Derived Normal), aliquot HCM-CSHL-0658-C20-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33cfc9c0-ab48-4b3b-8534-4bc6e7caa2ae

The open-access MAF lists 102 somatic variants for this specimen: 72 protein-altering or splice-affecting, 26 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 26, Nonsense Mutation 4, Frame Shift Del 3, Frame Shift Ins 2, 3'UTR 2, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4175C>A p.S1392* | Nonsense Mutation (SNP) | VAF 130/131 reads (99%) | catalogued as rs786204170, CM960068, CM990162, COSV57326586; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COCH | c.1345C>T p.R449C (on ENST00000216361 / NM_001347720.1; = p.R384C on NM_004086.3) | Missense Mutation (SNP) | VAF 254/402 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs756541797, COSV99363345; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.395A>G p.K132R | Missense Mutation (SNP) | VAF 253/253 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1057519996, COSV52666637, COSV52701687, COSV52759171; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABHD17A | c.410G>A p.R137H (on ENST00000292577 / NM_001130111.2; = p.R188H on NM_031213.4) | Missense Mutation (SNP) | VAF 80/637 reads (13%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.619); catalogued as rs765695569, COSV51751523; called by muse, mutect2, varscan2
- ADAM11 | c.1040G>T p.G347V | Missense Mutation (SNP) | VAF 74/544 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52345764; called by muse, mutect2
- ANK2 | c.11124C>A p.H3708Q | Missense Mutation (SNP) | VAF 192/304 reads (63%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.02); catalogued as rs753907196, COSV52196928; called by muse, mutect2, varscan2
- APC2 | c.2897G>A p.R966Q | Missense Mutation (SNP) | VAF 229/682 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs750620567; called by muse, mutect2, varscan2
- BEND3 | c.2428C>T p.R810C | Missense Mutation (SNP) | VAF 212/482 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1554231248; called by muse, mutect2, varscan2
- CALHM2 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 332/486 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs756784159, COSV53298020; called by muse, mutect2, varscan2
- CEP135 | c.1186G>A p.V396I | Missense Mutation (SNP) | VAF 108/291 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs757729898; called by muse, mutect2, varscan2
- CIITA | c.2495G>A p.R832H | Missense Mutation (SNP) | VAF 304/305 reads (100%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs778641112; called by muse, mutect2, varscan2
- CLSTN2 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 250/443 reads (56%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.895); catalogued as rs555082751, COSV71718074, COSV71720623; called by muse, mutect2, varscan2
- CR1 | c.5590G>A p.V1864I | Missense Mutation (SNP) | VAF 241/370 reads (65%) | SIFT tolerated (0.18); PolyPhen benign (0.167); catalogued as rs752517997; called by muse, mutect2, varscan2
- CRTAC1 | c.1927G>A p.V643I | Missense Mutation (SNP) | VAF 296/439 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs375513503; called by muse, mutect2, varscan2
- CYTIP | c.143C>T p.T48M | Missense Mutation (SNP) | VAF 32/270 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1198342027, COSV99938671; called by muse, mutect2, varscan2
- DCHS1 | c.6989G>A p.R2330H | Missense Mutation (SNP) | VAF 178/683 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.139); catalogued as rs200322732, COSV55031457; called by muse, mutect2, varscan2
- DNAH11 | c.4334G>A p.R1445Q | Missense Mutation (SNP) | VAF 154/336 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as rs751896015, COSV60951462; ClinVar: uncertain significance; called by muse, varscan2
- ESYT2 | c.1025G>A p.G342E (on ENST00000613624; = p.G266E on NM_020728.3) | Missense Mutation (SNP) | VAF 108/414 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV99276383; called by muse, mutect2, varscan2
- FSCB | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 297/440 reads (68%) | SIFT tolerated (0.44); PolyPhen benign (0.208); catalogued as COSV61218653; called by muse, mutect2, varscan2
- FSIP2 | c.8038dup p.T2680Nfs*9 | Frame Shift Ins (INS) | VAF 152/359 reads (42%) | catalogued as rs755234663; called by mutect2, varscan2
- KLHL12 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 207/311 reads (67%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.999); catalogued as COSV66127198; called by muse, varscan2
- LRRC37A2 | c.3881C>T p.T1294M | Missense Mutation (SNP) | VAF 369/1530 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs761469144; called by muse, mutect2, varscan2
- MAGI2 | c.2516G>A p.R839H | Missense Mutation (SNP) | VAF 130/554 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs199553094; called by muse, mutect2, varscan2
- MPP2 | c.1501C>T p.R501W (on ENST00000461854 / NM_001278372.2; = p.R477W on NM_005374.5) | Missense Mutation (SNP) | VAF 212/489 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs755167439, COSV52233492; called by muse, mutect2, varscan2
- MYOM2 | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 559/728 reads (77%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.599); catalogued as COSV100037255; called by muse, mutect2, varscan2
- NBEAL2 | c.5939G>A p.R1980H | Missense Mutation (SNP) | VAF 129/524 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774364793, COSV52758191; called by muse, mutect2, varscan2
- NKX1-1 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 446/675 reads (66%) | SIFT deleterious, low confidence (0.01); catalogued as rs980489640, COSV70026235; called by muse, mutect2, varscan2
- NPTX2 | c.323C>T p.T108M | Missense Mutation (SNP) | VAF 228/901 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1024300439; called by muse, mutect2, varscan2
- PANX2 | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 382/384 reads (99%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as rs1465503559; called by muse, varscan2
- PDIA2 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 308/308 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0.163); catalogued as rs202228688, COSV51988094; called by muse, mutect2, varscan2
- POLR1A | c.1284C>A p.F428L | Missense Mutation (SNP) | VAF 157/417 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.178); catalogued as rs1200182877; called by muse, mutect2, varscan2
- RYR1 | c.7153C>T p.R2385C | Missense Mutation (SNP) | VAF 201/593 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs202111332, COSV100615959; called by muse, mutect2, varscan2
- SALL3 | c.1915G>A p.V639I | Missense Mutation (SNP) | VAF 116/516 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs557725030; called by muse, mutect2, varscan2
- SLC39A3 | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 188/527 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs775552929, COSV54118817; called by muse, mutect2, varscan2
- SPTAN1 | c.6388C>T p.R2130C | Missense Mutation (SNP) | VAF 160/445 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as rs751337586, COSV63988208; called by muse, mutect2, varscan2
- SVEP1 | c.9947C>T p.T3316M | Missense Mutation (SNP) | VAF 256/389 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs201866666; called by muse, mutect2, varscan2
- TF | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 232/437 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as rs760468007, COSV53917816; called by muse, mutect2, varscan2
- TSSC4 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 299/655 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.049); catalogued as rs773913072; called by muse, mutect2, varscan2
- UNC5D | c.2013C>G p.D671E | Missense Mutation (SNP) | VAF 129/129 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV54846624; called by muse, mutect2, varscan2
- ZCCHC24 | c.440del p.C147Sfs*11 | Frame Shift Del (DEL) | VAF 96/322 reads (30%) | catalogued as COSV64886740; called by mutect2, pindel, varscan2
- ZFP14 | c.1051A>G p.I351V | Missense Mutation (SNP) | VAF 130/426 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs368590564; called by muse, mutect2, varscan2
- ZNF423 | c.572G>A p.R191Q (on ENST00000563137 / NM_001379286.1; = p.R183Q on NM_015069.4) | Missense Mutation (SNP) | VAF 252/261 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1473298259, COSV52194192; called by muse, mutect2, varscan2
- ABCA7 | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 266/406 reads (66%) | called by muse, mutect2, varscan2
- ADGRB3 | c.1196T>C p.V399A | Missense Mutation (SNP) | VAF 68/255 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- BEND5 | c.1184A>G p.K395R | Missense Mutation (SNP) | VAF 88/310 reads (28%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CCDC168 | c.11168A>C p.N3723T | Missense Mutation (SNP) | VAF 107/496 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- CCDC80 | c.2057T>C p.V686A | Missense Mutation (SNP) | VAF 202/388 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CER1 | c.53C>A p.T18K | Missense Mutation (SNP) | VAF 13/325 reads (4%) | SIFT tolerated (0.84); PolyPhen benign (0.001); called by muse, mutect2
- DACT3 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 195/609 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- DHX32 | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 238/372 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); called by muse, varscan2
- FBP1 | c.769C>A p.L257M | Missense Mutation (SNP) | VAF 245/372 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GTPBP2 | c.297G>T p.E99D | Missense Mutation (SNP) | VAF 282/562 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- HAO2 | c.190A>G p.I64V | Missense Mutation (SNP) | VAF 71/397 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRTAP19-4 | c.49G>C p.G17R | Missense Mutation (SNP) | VAF 57/445 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- LRP1B | c.5451G>T p.K1817N | Missense Mutation (SNP) | VAF 192/351 reads (55%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- MAGEA11 | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 285/285 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- NOS2 | c.3263C>T p.A1088V | Missense Mutation (SNP) | VAF 306/576 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- OR5D3P | c.254C>A p.T85K | Missense Mutation (SNP) | VAF 221/394 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- PIK3CD | c.151C>A p.H51N | Missense Mutation (SNP) | VAF 11/361 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.056); called by muse, mutect2
- PRB3 | c.340C>G p.P114A | Missense Mutation (SNP) | VAF 86/500 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PTPRB | c.2014G>T p.D672Y | Missense Mutation (SNP) | VAF 246/379 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- RBM33 | c.3179C>A p.A1060E | Missense Mutation (SNP) | VAF 197/339 reads (58%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- RP1 | c.2920C>A p.H974N | Missense Mutation (SNP) | VAF 70/430 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- SORCS1 | c.4G>T p.G2* | Nonsense Mutation (SNP) | VAF 123/342 reads (36%) | called by muse, mutect2, varscan2
- SPART | c.1377del p.I460Ffs*20 | Frame Shift Del (DEL) | VAF 257/612 reads (42%) | called by mutect2, pindel, varscan2
- STRIP2 | c.1307G>A p.S436N | Missense Mutation (SNP) | VAF 95/384 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TIAM1 | c.921C>G p.S307R | Missense Mutation (SNP) | VAF 140/355 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- TM7SF3 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 132/214 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- TRAPPC11 | c.666_669del p.F223Lfs*7 | Frame Shift Del (DEL) | VAF 95/150 reads (63%) | called by mutect2, pindel, varscan2
- TRIO | c.1081G>A p.G361S | Missense Mutation (SNP) | VAF 183/183 reads (100%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- ZFHX4 | c.300C>A p.C100* | Nonsense Mutation (SNP) | VAF 119/529 reads (22%) | called by muse, mutect2, varscan2
- ZNF384 | c.1532_1536dup p.Q513Sfs*38 (on ENST00000361959; = p.Q452Sfs*38 on NM_133476.5) | Frame Shift Ins (INS) | VAF 122/511 reads (24%) | called by pindel, varscan2
- ADRA1B | c.411C>T p.C137= | Silent (SNP) | VAF 290/450 reads (64%) | catalogued as rs147604848; called by muse, mutect2, varscan2
- AP000721.1 | c.207G>A p.G69= | Silent (SNP) | VAF 282/649 reads (43%) | called by muse, mutect2, varscan2
- CCR6 | c.705G>A p.T235= | Silent (SNP) | VAF 155/398 reads (39%) | catalogued as rs775586288, COSV59473854; called by muse, mutect2, varscan2
- CHST2 | c.1131C>T p.G377= | Silent (SNP) | VAF 267/561 reads (48%) | catalogued as COSV100535818; called by muse, mutect2, varscan2
- CPED1 | c.2736C>T p.N912= | Silent (SNP) | VAF 32/245 reads (13%) | called by muse, mutect2, varscan2
- CSMD3 | c.10194G>A p.T3398= (on ENST00000297405 / NM_001363185.1; = p.T3229= on NM_052900.3) | Silent (SNP) | VAF 266/678 reads (39%) | catalogued as rs762493390; called by muse, mutect2, varscan2
- DMTF1 | c.756G>A p.A252= | Silent (SNP) | VAF 150/634 reads (24%) | catalogued as rs748180758, COSV58685384; called by muse, mutect2, varscan2
- FCRL1 | c.675G>A p.L225= | Silent (SNP) | VAF 219/220 reads (100%) | called by muse, mutect2, varscan2
- FMNL2 | c.2343G>A p.K781= | Silent (SNP) | VAF 133/469 reads (28%) | called by muse, mutect2, varscan2
- FZD1 | c.1566C>T p.H522= | Silent (SNP) | VAF 245/514 reads (48%) | catalogued as COSV55313017; called by muse, mutect2, varscan2
- GREB1 | c.2457G>A p.P819= | Silent (SNP) | VAF 293/615 reads (48%) | catalogued as rs532106359, COSV52190608; called by muse, mutect2, varscan2
- HMCN1 | c.12570C>T p.C4190= | Silent (SNP) | VAF 269/382 reads (70%) | catalogued as rs375085364; called by muse, mutect2, varscan2
- INSIG1 | c.168T>A p.A56= | Silent (SNP) | VAF 310/826 reads (38%) | called by muse, mutect2, varscan2
- KCNE4 | c.474G>A p.E158= | Silent (SNP) | VAF 259/613 reads (42%) | catalogued as rs1277552430; called by muse, mutect2, varscan2
- KEL | c.303C>T p.T101= | Silent (SNP) | VAF 194/724 reads (27%) | catalogued as rs778069705, COSV62333058; called by muse, mutect2, varscan2
- KIF1B | c.3846G>A p.G1282= (on ENST00000377086 / NM_001365952.1; = p.G1236= on NM_015074.3) | Silent (SNP) | VAF 53/216 reads (25%) | catalogued as rs374156057; called by muse, mutect2, varscan2
- MAST1 | c.2280C>T p.T760= | Silent (SNP) | VAF 153/437 reads (35%) | catalogued as rs967544500; called by muse, mutect2, varscan2
- NSD3 | c.1878C>T p.S626= | Silent (SNP) | VAF 1343/1454 reads (92%) | catalogued as rs1329604574; called by muse, mutect2
- PCDHA7 | c.2307C>T p.L769= | Silent (SNP) | VAF 182/293 reads (62%) | called by muse, mutect2, varscan2
- PDE6B | c.408C>T p.I136= | Silent (SNP) | VAF 254/401 reads (63%) | catalogued as rs755515613, COSV55330589; called by muse, mutect2, varscan2
- RFX8 | c.1266G>A p.P422= (on ENST00000646446; = p.P351= on NM_001145664.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 96/575 reads (17%) | catalogued as rs1207045591; called by muse, mutect2, varscan2
- SALL1 | c.3750C>T p.N1250= | Silent (SNP) | VAF 314/314 reads (100%) | catalogued as rs142653419; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSC22D2 | c.681A>G p.V227= | Silent (SNP) | VAF 314/580 reads (54%) | catalogued as rs1223796449; called by muse, mutect2, varscan2
- VIT | c.456C>T p.Y152= | Silent (SNP) | VAF 248/521 reads (48%) | catalogued as rs17855107; called by muse, mutect2, varscan2
- VSIG1 | c.666C>T p.C222= | Silent (SNP) | VAF 230/230 reads (100%) | catalogued as rs764140353, COSV54259760; called by muse, mutect2, varscan2
- ZNF541 | c.1557C>T p.P519= | Silent (SNP) | VAF 144/498 reads (29%) | catalogued as rs888939402; called by muse, mutect2, varscan2
- CCDC40 | c.2832+342C>T | Intron (SNP) | VAF 262/876 reads (30%) | catalogued as COSV100884366; called by muse, varscan2
- FGFR2 | c.*196_*198del | 3'UTR (DEL) | VAF 180/324 reads (56%) | called by pindel, varscan2
- KLC2 | c.*749C>G | 3'UTR (SNP) | VAF 305/647 reads (47%) | catalogued as rs564644328; called by muse, mutect2, varscan2
- SERF2 | chr15:43798964 A>G | 3'Flank (SNP) | VAF 78/417 reads (19%) | called by muse, mutect2, varscan2
